CCDI case PBBYLT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/6551a8fa-56c2-41b3-9fdd-c3843d91434d

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Papillary carcinoma, NOS: ICD-O-3 morphology code: 8050/3; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 14.7 years (5,372 days).

Biospecimens (3 samples)
- Sample 0DOO1G: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DOO1J: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DOOCS: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
